Gene-level copy-number profile of specimen HCM-CSHL-0821-C19-85M from HCMI case HCM-CSHL-0821-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 61.0 years (22,269 days).
Specimen HCM-CSHL-0821-C19-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0cc933b4-6355-4dc6-ba34-949476135f60.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0821-C19-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/49c7e825-d6cf-4d75-9804-a4c772879b1e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 11,212; copy number 2: 25,773; copy number 3: 18,537; copy number 4: 79; copy number 5: 2,784; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:70,751,184–70,795,914, 2 genes: GUSBP16, AC139272.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,785 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:18,467,172–114,337,626, 1,330 genes, copy number 5 (broad region; genes not listed).
- chr15:20,835,372–20,893,980, 4 genes, copy number 5: POTEB2, RNU6-749P, AC012414.5, AC037471.2.
- chr15:20,916,686–21,015,078, 4 genes, copy number 5–6: NF1P1, MIR5701-1, OR11J5P, IGHD2OR15-2B.
- chr15:21,053,004–21,054,702, 1 gene, copy number 5: AC037471.1.
- chr16:16,541,217–16,541,847, 1 gene, copy number 5: AC136619.2.
- chr16:25,419,812–35,912,516, 524 genes, copy number 5 (broad region; genes not listed).
- chr20:24,469,629–24,666,616, 1 gene, copy number 5 (within-gene range 1–5): SYNDIG1.
- chr20:24,679,547–64,327,972, 920 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,212. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
